Surgical pathology report (de-identified scan), TCGA case TCGA-DK-AA6U, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-AA6U-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: (Age:

Gender: M

Ref. Physician:

Patient Address:

Location:

Service: Urology

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Bladder tumor

*ICD O3
Carcinoma, urothelial NOS 8120/3
Site: 4 Bladder, lateral wall 167.2
Op 4/30/14*

Specimens Submitted:

1: Right lateral bladder wall

2: Left bladder neck resection

DIAGNOSIS:

1. Right lateral bladder wall:

Tumor Type:

Invasive urothelial carcinoma, NOS

Pattern of growth of the non-invasive component:

Papillary and flat

Local Invasion:

Lamina propria (focal and superficial)

Muscularis Propria:

Muscularis propria is not involved

Vascular Invasion:

Not identified

2. Left bladder neck resection:

Tumor Type:

Invasive urothelial carcinoma, NOS

Pattern of growth of the non-invasive component:

Papillary and flat

Local Invasion:

Muscularis propria

The tumor also involves peri-urethral glands

Vascular Invasion:

Identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Gross Description:

- 1) The specimen is received in labeled "Right lateral bladder wall", and consists of multiple pieces of tan soft tissue measuring 1 x 1 x 0.3 cm in aggregate. The specimen is entirely submitted in one cassette. Summary of sections:
- 2) The specimen is received in labeled "Left bladder neck resection", and consists of multiple pieces of tan soft tissue measuring 1 x 1 x 0.5 cm in aggregate. The specimen is entirely submitted in one cassette. Summary of sections:

Summary of Sections:

Part 1: Right lateral bladder wall

Blocks	Block Designation	PCs
1		5

Part 2: Left bladder neck resection

Blocks	Block Designation	PCs
1		8

Source: NCI Genomic Data Commons file 865f7767-f9c9-4b4b-a129-855bc8fc063a (TCGA-DK-AA6U.BC479C80-74F1-417F-BEE4-6C69975C0BF6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).